Gene-level copy-number profile of tumor specimen TCGA-36-1578-01A from TCGA case TCGA-36-1578, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 63.9 years (23,329 days).
Specimen TCGA-36-1578-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.236d5b82-7332-40a1-aadc-158e8302b923.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-1578-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/31fb186e-343e-4b8f-a5b0-308f42ad4985

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 177; copy number 1: 5,526; copy number 2: 21,653; copy number 3: 21,686; copy number 4: 7,353; copy number 5: 3,074; copy number 6: 203; copy number 7: 131.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-1578-01): tumor purity 0.81, ploidy 2.57, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 177 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:163,524,298–164,384,050, 1 gene (within-gene range 0–2): MARCHF1.
- chr4:163,828,800–168,928,457, 64 genes (within-gene range 0–1) (broad region; genes not listed).
- chr7:7,640,711–8,004,053, 2 genes (within-gene range 0–2): UMAD1, AC007161.3.
- chr7:7,906,519–19,002,416, 110 genes (within-gene range 0–6) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 131 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,909,574–13,980,437, 1 gene, copy number 7 (within-gene range 5–7): ANKRD20A11P.
- chr21:13,968,489–23,490,724, 130 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,526. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
